Somatic mutation profile of tumor specimen MMRF_1882_1_BM_CD138pos (aliquot MMRF_1882_1_BM_CD138pos_T1_KBS5U_L05789) from MMRF case MMRF_1882, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.1 years (24,522 days).
Specimen MMRF_1882_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09821ce2-8ff0-45c4-8e66-9e621244e43b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1882_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1882_1_PB_Whole_C3_KBS5U_L05809; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78010877-87f2-46da-9f2d-0a4f5e02288c

The open-access MAF lists 164 somatic variants for this specimen: 60 protein-altering or splice-affecting, 17 silent, 87 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 50, Missense Mutation 48, Silent 17, Intron 13, 5'UTR 9, 5'Flank 6, RNA 6, Nonsense Mutation 4, 3'Flank 3, Splice Region 3, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALCAM | c.1279A>G p.S427G | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.061); catalogued as rs1164311315; called by muse, mutect2, varscan2
- ARMC9 | c.1716C>T p.S572= | Splice Region (SNP) | VAF 10/130 reads (8%) | catalogued as rs758177199, COSV63020011; called by muse, mutect2
- ATP2B2 | c.1903C>T p.R635C (on ENST00000352432; = p.R601C on NM_001683.5) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs74592691; called by muse, mutect2, varscan2
- C19orf12 | c.256C>G p.Q86E (on ENST00000392278 / NM_001031726.3; = p.Q75E on NM_031448.6) | Missense Mutation (SNP) | VAF 20/376 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.205); catalogued as CM132609; called by muse, mutect2
- CEP126 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.852); catalogued as rs757955825, COSV54831087; called by muse, mutect2, varscan2
- COL27A1 | c.4745C>T p.S1582L | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as rs766382533, COSV61927058; called by muse, mutect2, varscan2
- DUSP2 | c.727A>G p.I243V | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs753164081; called by muse, mutect2, varscan2
- EHMT2 | c.2984G>A p.W995* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as rs777561342; called by muse, mutect2
- FGF13 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV65432871; called by muse, mutect2, varscan2
- GRIN2B | c.3964G>A p.V1322I | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.503); catalogued as rs200255226, COSV74204762; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- IGLL5 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.019); catalogued as rs545109780, COSV101597155; called by muse, varscan2
- IGLV3-1 | c.146A>G p.K49R | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs61731694; called by muse, varscan2
- IGLV3-1 | c.212A>T p.K71M | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as rs537636882; called by muse, varscan2
- IPO11 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.548); catalogued as rs1336545451; called by muse, mutect2, varscan2
- LRRC8D | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs147514186; called by muse, mutect2, varscan2
- MFSD4A | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1341941837, COSV65657007; called by muse, mutect2
- MGAT4C | c.1300G>T p.E434* | Nonsense Mutation (SNP) | VAF 31/76 reads (41%) | catalogued as COSV59830943, COSV59831532; called by muse, mutect2, varscan2
- MYH1 | c.3760C>T p.R1254C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1291893077, COSV56849076, COSV56850582; called by muse, mutect2, varscan2
- NIPBL | c.3574+1G>A p.X1192_splice | Splice Site (SNP) | VAF 8/79 reads (10%) | catalogued as COSV99242237; called by muse, mutect2, varscan2
- PDCL3 | c.616A>G p.T206A | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs202185256; called by muse, mutect2, varscan2
- PPFIA4 | c.1895C>T p.T632M (on ENST00000447715; = p.T633M on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs565283433, COSV55314310; called by muse, mutect2, varscan2
- PRKCB | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.783); catalogued as rs371650623, COSV57774078; called by muse, mutect2, varscan2
- RAB19 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.772); catalogued as rs568276754, COSV52045883; called by muse, mutect2, varscan2
- SRGAP3 | c.1876G>A p.V626M | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs547978979; called by muse, mutect2, varscan2
- ST8SIA5 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 33/225 reads (15%) | PolyPhen probably damaging (0.934); catalogued as rs765111904, COSV100164887; called by muse, mutect2, varscan2
- STIM1 | c.1475-3C>T | Splice Region (SNP) | VAF 9/77 reads (12%) | catalogued as rs1382037379; called by muse, mutect2, varscan2
- TDO2 | c.317G>T p.R106M | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV72232653; called by muse, mutect2, varscan2
- TMEM161A | c.1282C>T p.Q428* | Nonsense Mutation (SNP) | VAF 5/40 reads (13%) | catalogued as rs1238691467; called by muse, mutect2, varscan2
- AC019068.1 | n.397G>C | Splice Region (SNP) | VAF 23/252 reads (9%) | called by muse, mutect2
- ACTG1 | c.121C>A p.Q41K | Missense Mutation (SNP) | VAF 94/195 reads (48%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- AHNAK | c.9233A>G p.K3078R | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); called by muse, mutect2
- BICD1 | c.2386G>T p.D796Y | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C17orf97 | c.414A>C p.K138N | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- CAVIN1 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CTR9 | c.1729G>T p.A577S | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CUBN | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2
- CYFIP2 | c.1008G>C p.Q336H | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.585); called by muse, varscan2
- DEFB129 | c.274G>T p.V92L | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DEPDC7 | c.1096G>A p.A366T (on ENST00000241051 / NM_001077242.2; = p.A357T on NM_139160.2) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- DNAH2 | c.7957T>G p.S2653A | Missense Mutation (SNP) | VAF 92/206 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EFCAB13 | c.121_122del p.K41Vfs*3 | Frame Shift Del (DEL) | VAF 11/68 reads (16%) | called by mutect2, pindel
- ENPP3 | c.821C>G p.S274* | Nonsense Mutation (SNP) | VAF 15/134 reads (11%) | called by muse, mutect2
- FAM169A | c.1907_1909del p.S636_S637delinsT | In Frame Del (DEL) | VAF 37/301 reads (12%) | called by mutect2, pindel, varscan2
- FOXS1 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GNAI2 | c.151A>G p.K51E | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- HECW1 | c.4199C>A p.T1400K | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.471); called by muse, mutect2
- HMCN1 | c.2578A>C p.S860R | Missense Mutation (SNP) | VAF 79/164 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- HSPA4L | c.2516A>T p.D839V | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- LGI4 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- LRRC8D | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MORC4 | c.1210dup p.T404Nfs*5 | Frame Shift Ins (INS) | VAF 33/70 reads (47%) | called by mutect2, pindel, varscan2
- MYCBP2 | c.9530C>T p.A3177V (on ENST00000357337; = p.A3215V on NM_015057.5) | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP2 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- OR10G7 | c.775C>G p.L259V | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- OXCT1 | c.1051G>C p.G351R | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- R3HDM1 | c.1580C>A p.P527Q | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- RBM25 | c.1345A>C p.K449Q | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- TACR2 | c.937A>T p.R313W | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VWA5A | c.503C>G p.T168S | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.094); called by muse, mutect2
- ZNF30 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- ADAMTS10 | c.117T>C p.Y39= | Silent (SNP) | VAF 41/168 reads (24%) | called by muse, mutect2, varscan2
- ANXA9 | c.21G>A p.K7= | Silent (SNP) | VAF 11/95 reads (12%) | called by muse, mutect2, varscan2
- DARS1 | c.192A>G p.A64= | Silent (SNP) | VAF 12/306 reads (4%) | called by muse, mutect2
- IGHV1-69 | c.336G>C p.V112= | Silent (SNP) | VAF 34/109 reads (31%) | catalogued as rs782427576; called by muse, mutect2, varscan2
- IGHV1-69D | c.336G>C p.V112= | Silent (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- IGKV4-1 | c.87C>T p.D29= | Silent (SNP) | VAF 22/24 reads (92%) | catalogued as rs370905182; called by muse, mutect2
- IGLL5 | c.165A>G p.S55= | Silent (SNP) | VAF 14/21 reads (67%) | called by muse, varscan2
- KIF20B | c.3828A>T p.A1276= (on ENST00000371728 / NM_001284259.2; = p.A1236= on NM_016195.4) | Silent (SNP) | VAF 21/153 reads (14%) | called by muse, mutect2, varscan2
- MACC1 | c.795T>G p.L265= | Silent (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2
- MST1R | c.177G>T p.V59= | Silent (SNP) | VAF 18/282 reads (6%) | called by muse, mutect2
- NKX1-1 | c.1323C>T p.P441= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs966466939; called by muse, mutect2, varscan2
- PLEKHB1 | c.570C>T p.R190= | Silent (SNP) | VAF 54/107 reads (50%) | called by muse, mutect2, varscan2
- PPAT | c.1155T>A p.I385= | Silent (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- SRGN | c.204C>T p.P68= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV54345820; called by muse, mutect2, varscan2
- TRIM27 | c.1191A>T p.G397= | Silent (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- USP54 | c.1128C>T p.Y376= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs761473573; called by muse, mutect2, varscan2
- VSIG10L | c.1563C>A p.A521= | Silent (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- ABHD2 | c.*6375G>A | 3'UTR (SNP) | VAF 44/127 reads (35%) | catalogued as rs1329391126, COSV61775129; called by muse, mutect2, varscan2
- AC009093.3 | n.1489T>C | RNA (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- AC024651.2 | chr15:97874745 C>T | 5'Flank (SNP) | VAF 7/137 reads (5%) | catalogued as rs977690894; called by muse, mutect2
- ACTR3 | c.*3257C>T | 3'UTR (SNP) | VAF 13/72 reads (18%) | catalogued as rs1288877250; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849363 G>A | 5'Flank (SNP) | VAF 24/77 reads (31%) | called by muse, mutect2, varscan2
- AOX1 | c.*2T>A | 3'UTR (SNP) | VAF 92/209 reads (44%) | called by muse, mutect2, varscan2
- C21orf58 | c.*492G>A | 3'UTR (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- CCDC152 | c.*898G>A | 3'UTR (SNP) | VAF 16/182 reads (9%) | called by muse, mutect2
- CCER1 | c.*669A>G | 3'UTR (SNP) | VAF 18/52 reads (35%) | called by muse, mutect2, varscan2
- CCR1 | c.*170G>A | 3'UTR (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- CDK2AP2 | c.*33A>G | 3'UTR (SNP) | VAF 7/91 reads (8%) | catalogued as rs1488768379; called by muse, mutect2
- CDON | c.*3606C>A | 3'UTR (SNP) | VAF 90/148 reads (61%) | called by muse, mutect2, varscan2
- CHCHD7 | c.-16-100T>C | Intron (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2
- CLCN1 | c.774+235C>A | Intron (SNP) | VAF 36/268 reads (13%) | called by muse, mutect2, varscan2
- CLMP | c.-214G>A | 5'UTR (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- CPT1A | c.*1389del | 3'UTR (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- CRIM1 | c.*932T>A | 3'UTR (SNP) | VAF 10/57 reads (18%) | catalogued as rs1006935200, COSV54863489; called by muse, mutect2, varscan2
- DACH2 | c.*262C>A | 3'UTR (SNP) | VAF 30/34 reads (88%) | called by muse, varscan2
- DACH2 | c.*311A>T | 3'UTR (SNP) | VAF 24/26 reads (92%) | called by muse, varscan2
- DDX12P | n.1961T>C | RNA (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- DEPDC1 | c.*519_*520dup | 3'UTR (INS) | VAF 46/145 reads (32%) | called by mutect2, varscan2
- DNAJC27 | chr2:24972124 del C | 5'Flank (DEL) | VAF 4/37 reads (11%) | called by mutect2, pindel
- DPF2 | c.*475C>T | 3'UTR (SNP) | VAF 16/149 reads (11%) | catalogued as rs1243197463; called by muse, mutect2, varscan2
- DUSP12 | c.*118A>T | 3'UTR (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2
- EPM2A | chr6:145735820 A>C | 5'Flank (SNP) | VAF 27/66 reads (41%) | called by muse, mutect2, varscan2
- ERAP2 | c.*1185A>C | 3'UTR (SNP) | VAF 37/155 reads (24%) | called by muse, mutect2, varscan2
- ERGIC2 | c.*667C>T | 3'UTR (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- FBXL18 | c.-68C>A | 5'UTR (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- FERMT1 | c.*604G>C | 3'UTR (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- GABRA1 | c.-16+564T>C | Intron (SNP) | VAF 170/232 reads (73%) | catalogued as rs1344359664; called by muse, mutect2, varscan2
- GLDN | c.*1725T>C | 3'UTR (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2
- GTDC1 | c.*512G>T | 3'UTR (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2
- HYAL2 | c.-47+1018C>T | Intron (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
- ICE2 | c.*2637G>A | 3'UTR (SNP) | VAF 25/106 reads (24%) | called by muse, mutect2, varscan2
- IGLL5 | c.-213A>G | 5'UTR (SNP) | VAF 21/50 reads (42%) | catalogued as COSV73250972; called by muse, varscan2
- IGLL5 | c.-157G>T | 5'UTR (SNP) | VAF 30/54 reads (56%) | called by muse, varscan2
- IGLL5 | c.-156G>C | 5'UTR (SNP) | VAF 31/55 reads (56%) | catalogued as COSV73251062; called by muse, varscan2
- IGLL5 | c.-22G>T | 5'UTR (SNP) | VAF 29/59 reads (49%) | called by muse, mutect2, varscan2
- IL34 | c.-193G>A | 5'UTR (SNP) | VAF 14/54 reads (26%) | catalogued as rs1475765295; called by muse, mutect2, varscan2
- INHBB | c.*742G>A | 3'UTR (SNP) | VAF 7/69 reads (10%) | catalogued as rs1323301582; called by muse, mutect2, varscan2
- INO80D | c.*1542_*1543dup | 3'UTR (INS) | VAF 14/58 reads (24%) | catalogued as rs1204652444; called by mutect2, varscan2
- ISX | c.*9C>A | 3'UTR (SNP) | VAF 43/214 reads (20%) | called by muse, mutect2, varscan2
- JDP2 | chr14:75472733 T>C | 3'Flank (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- LAPTM4B | c.*1418T>A | 3'UTR (SNP) | VAF 16/126 reads (13%) | called by muse, mutect2
- LCORL | c.*1750T>A | 3'UTR (SNP) | VAF 35/74 reads (47%) | called by muse, mutect2, varscan2
- LEMD1 | c.*171C>G | 3'UTR (SNP) | VAF 13/59 reads (22%) | catalogued as rs368365515; called by muse, mutect2, varscan2
- LGALS8 | chr1:236551869 C>A | 3'Flank (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- LINC01973 | n.1575C>T | RNA (SNP) | VAF 9/93 reads (10%) | called by muse, mutect2
- LTBP2 | c.*1299T>G | 3'UTR (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2, varscan2
- MELTF | c.712+1676A>C | Intron (SNP) | VAF 95/196 reads (48%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851384 G>A | 5'Flank (SNP) | VAF 58/124 reads (47%) | catalogued as rs748733160; called by muse, mutect2, varscan2
- MRPL44 | c.*605G>C | 3'UTR (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- MTM1 | c.136+129A>G | Intron (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- MYO10 | c.*157C>T | 3'UTR (SNP) | VAF 16/169 reads (9%) | catalogued as rs1359677560; called by muse, mutect2, varscan2
- NCAN | c.-34C>T | 5'UTR (SNP) | VAF 15/150 reads (10%) | called by muse, mutect2
- NPR3 | c.*5371G>A | 3'UTR (SNP) | VAF 15/112 reads (13%) | called by muse, mutect2, varscan2
- PAPOLA | c.*1689_*1691del | 3'UTR (DEL) | VAF 16/77 reads (21%) | called by mutect2, pindel*, varscan2*
- PBX2 | c.*750_*758del | 3'UTR (DEL) | VAF 22/62 reads (35%) | called by mutect2, pindel, varscan2
- PCDH7 | c.*465A>T | 3'UTR (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- PDE4A | c.320+9987C>G | Intron (SNP) | VAF 76/152 reads (50%) | called by muse, mutect2, varscan2
- PLEKHA1 | c.*609G>A | 3'UTR (SNP) | VAF 9/164 reads (5%) | called by muse, mutect2
- PPIG | c.*585G>C | 3'UTR (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- PRAMEF12 | c.*259C>T | 3'UTR (SNP) | VAF 21/260 reads (8%) | catalogued as rs1252924771, COSV63216563; called by muse, mutect2
- PSD2 | c.*1037G>C | 3'UTR (SNP) | VAF 44/86 reads (51%) | called by muse, mutect2, varscan2
- PSEN1 | c.*4321C>A | 3'UTR (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- PTPN6 | c.1674-83G>T | Intron (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- RNF217-AS1 | n.932C>T | RNA (SNP) | VAF 16/100 reads (16%) | catalogued as rs138521906; called by muse, mutect2, varscan2
- SACS | c.*1231G>T | 3'UTR (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- SCN1A | c.*1593T>G | 3'UTR (SNP) | VAF 46/101 reads (46%) | called by muse, mutect2, varscan2
- SIRPB1 | c.76+8341C>T | Intron (SNP) | VAF 12/37 reads (32%) | catalogued as rs755774584; called by muse, mutect2, varscan2
- SMAP1 | chr6:70667873 G>A | 5'Flank (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2
- SRSF10 | c.*1051G>A | 3'UTR (SNP) | VAF 18/125 reads (14%) | called by muse, mutect2, varscan2
- STAT3 | c.*1266G>T | 3'UTR (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- STK3 | c.*862_*863del | 3'UTR (DEL) | VAF 6/49 reads (12%) | called by mutect2, pindel, varscan2
- STK32B | c.*974A>C | 3'UTR (SNP) | VAF 10/74 reads (14%) | catalogued as COSV51475726; called by muse, mutect2, varscan2
- SYNPO | chr5:150658467 C>T | 3'Flank (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2
- TCEANC2 | c.-42-256A>G | Intron (SNP) | VAF 22/95 reads (23%) | catalogued as rs968609764; called by muse, mutect2, varscan2
- TK2 | c.64-4891G>T | Intron (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- TMPRSS11BNL | n.256T>A | RNA (SNP) | VAF 24/123 reads (20%) | called by muse, mutect2, varscan2
- TPH2 | c.*79A>G | 3'UTR (SNP) | VAF 23/118 reads (19%) | called by muse, mutect2, varscan2
- TSC2 | c.3884-16G>A | Intron (SNP) | VAF 6/52 reads (12%) | catalogued as rs544004178, COSV54771534; ClinVar: likely benign; called by muse, mutect2, varscan2
- UFM1 | c.*524_*526del | 3'UTR (DEL) | VAF 18/30 reads (60%) | called by mutect2, pindel, varscan2
- VAPB | c.*6266C>T | 3'UTR (SNP) | VAF 11/83 reads (13%) | catalogued as rs1050741057; called by muse, mutect2, varscan2
- WNT5A | c.*4079T>C | 3'UTR (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2
- ZFYVE19 | c.1338-19G>A | Intron (SNP) | VAF 17/107 reads (16%) | called by muse, mutect2, varscan2
- ZNF43 | c.-52G>A | 5'UTR (SNP) | VAF 42/168 reads (25%) | catalogued as rs367555667; called by muse, mutect2, varscan2
- ZNF725P | n.363C>A | RNA (SNP) | VAF 18/528 reads (3%) | called by muse, mutect2
